Somatic mutation profile of tumor specimen TCGA-74-6578-01A (aliquot TCGA-74-6578-01A-11D-1845-08) from TCGA case TCGA-74-6578, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.8 years (21,464 days).
Specimen TCGA-74-6578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a9b13bc-d23a-436f-8da9-e2895ed88187.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-74-6578-10A (Blood Derived Normal), aliquot TCGA-74-6578-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5466be78-b711-4c31-b2ca-913ffe75fbf2

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 15, Intron 3, Splice Site 2, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 26/94 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAMDC | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV59020388; called by muse, mutect2, varscan2
- ABCC9 | c.3283C>T p.R1095C | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752450127, COSV53971662, COSV53981868; called by muse, mutect2, varscan2
- ARHGEF28 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs754962592, COSV55256803; called by muse, mutect2, varscan2
- BCL9 | c.1712C>G p.S571C | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV52348442, COSV52348730; called by muse, mutect2, varscan2
- BTBD1 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV55603889, COSV55604236; called by muse, mutect2, varscan2
- CENPC | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs773803780, COSV56625389; called by muse, mutect2, varscan2
- CFAP74 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV54568595, COSV54572173; called by muse, mutect2
- CST9 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.061); catalogued as COSV65402857; called by muse, mutect2, varscan2
- DACH2 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV64181214; called by muse, mutect2, varscan2
- DHCR7 | c.1079T>A p.L360Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as CM042972, COSV62796311; called by muse, mutect2, varscan2
- DNAH3 | c.6673A>T p.S2225C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV54542653; called by muse, mutect2, varscan2
- DOCK5 | c.2955C>A p.F985L | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV52408627; called by muse, mutect2, varscan2
- ENPP7 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs142610423; called by muse, mutect2, varscan2
- EPHA10 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431663148, COSV57626286; called by muse, mutect2, varscan2
- FAM78B | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57981003; called by muse, mutect2, varscan2
- FRAS1 | c.4952G>A p.R1651Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377123833; called by muse, mutect2, varscan2
- GLDC | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761957837, CM1510120, COSV58678266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIP1 | c.2262G>C p.Q754H (on ENST00000359742 / NM_001379345.1; = p.Q702H on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1014683071, COSV54036745; called by muse, mutect2, varscan2
- HAO2 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58041506; called by muse, mutect2, varscan2
- HPX | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs566505317, COSV56420308; called by mutect2, varscan2
- HRNR | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773195834, COSV64261297; called by muse, mutect2, varscan2
- KCTD19 | c.1870A>G p.T624A | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58574425; called by muse, mutect2, varscan2
- KIF2B | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as rs774999118, COSV52129324; called by muse, mutect2, varscan2
- LAMP1 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60212554, COSV60212883; called by muse, mutect2, varscan2
- MMEL1 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1168551929, COSV56524904; called by muse, mutect2, varscan2
- MUC16 | c.33878C>T p.P11293L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1452700787, COSV67484082; called by muse, mutect2, varscan2
- NOTCH2 | c.1108+1G>A p.X370_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV56701400; called by muse, mutect2
- NOXA1 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs746385829, COSV58163276; called by muse, mutect2, varscan2
- OR4K1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs368279248; called by muse, mutect2, varscan2
- PAX5 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63905553; called by muse, mutect2, varscan2
- PLBD1 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV53695388; called by muse, mutect2, varscan2
- PLEC | c.12065T>C p.F4022S (on ENST00000322810 / NM_201380.4; = p.F3912S on NM_000445.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59677719; called by muse, mutect2, varscan2
- PNPT1 | c.1602G>C p.L534F | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53179254; called by muse, mutect2, varscan2
- RHAG | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs77467572, COSV57705744; called by muse, mutect2, varscan2
- SENP7 | c.1550A>C p.D517A | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV58616646; called by muse, mutect2, varscan2
- SGSM2 | c.1774A>G p.M592V (on ENST00000426855 / NM_001098509.2; = p.M637V on NM_014853.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV52160758; called by muse, mutect2, varscan2
- SLC1A6 | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.525); catalogued as COSV55672865; called by muse, mutect2, varscan2
- SLC36A2 | c.23A>T p.E8V | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV58864576; called by muse, mutect2, varscan2
- SLC5A7 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); catalogued as rs1214276413, COSV50893520, COSV50898556; called by muse, mutect2, varscan2
- SLC6A14 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 82/119 reads (69%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782404299, COSV64141364; called by muse, mutect2, varscan2
- SPAG1 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV52562170; called by muse, mutect2, varscan2
- TGM5 | c.2156C>T p.A719V (on ENST00000220420 / NM_201631.4; = p.A637V on NM_004245.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV55011631; called by muse, mutect2, varscan2
- TMEM120B | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770585789, COSV61185409; called by muse, mutect2, varscan2
- TNNT1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs376309451; called by muse, mutect2, varscan2
- TTC14 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV56009568; called by muse, mutect2, varscan2
- TXLNA | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 31/115 reads (27%) | catalogued as COSV65315020; called by muse, mutect2, varscan2
- UGT2B7 | c.1568C>G p.A523G | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1349721571, COSV100535251, COSV59445021; called by muse, mutect2, varscan2
- ZBTB7B | c.82C>T p.R28C (on ENST00000292176; = p.R62C on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52694316; called by muse, mutect2, varscan2
- ZNF697 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70284281; called by muse, mutect2
- CYLC2 | c.239del p.S80Ffs*2 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by mutect2, pindel, varscan2
- SMC3 | c.1773_1775del p.N591del | In Frame Del (DEL) | VAF 21/40 reads (53%) | called by mutect2, pindel, varscan2
- CELSR1 | c.825C>T p.G275= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs748393769, COSV53095064; called by muse, mutect2, varscan2
- COL1A2 | c.981C>T p.R327= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs141762645; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- DSP | c.2469G>A p.S823= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as rs368945617; ClinVar: likely benign; called by muse, mutect2, varscan2
- FER1L6 | c.5412G>A p.S1804= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as rs374383727; called by muse, mutect2, varscan2
- FNTA | c.870C>T p.S290= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV56491255; called by muse, mutect2, varscan2
- FZD5 | c.1269C>T p.F423= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV54942986; called by muse, mutect2, varscan2
- LILRB5 | c.1092G>A p.P364= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs774056299, COSV100300727, COSV60260114; called by muse, mutect2, varscan2
- MACF1 | c.19539G>A p.Q6513= (on ENST00000372915; = p.Q4558= on NM_012090.5) | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV57137057; called by muse, mutect2, varscan2
- NCAPD3 | c.2640G>A p.Q880= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV73258560; called by muse, mutect2, varscan2
- PKP2 | c.1740C>T p.D580= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs397517006, COSV50742355; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN5A | c.6045C>T p.I2015= (on ENST00000333535 / NM_198056.3; = p.I2014= on NM_000335.5) | Silent (SNP) | VAF 47/143 reads (33%) | catalogued as rs766459103, COSV61136632; called by muse, mutect2, varscan2
- TLR6 | c.906G>A p.T302= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs371809071; called by muse, mutect2, varscan2
- TPTE | c.1650C>T p.S550= (on ENST00000618007 / NM_199261.4; = p.S532= on NM_199259.4) | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs774949669; called by muse, mutect2, varscan2
- UBA3 | c.270G>A p.L90= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV62741200; called by muse, mutect2, varscan2
- USP30 | c.513G>A p.S171= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs1216185152, COSV57450931; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-926G>A | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as rs41306564, COSV60824617; called by muse, varscan2
- EYA4 | c.1757-134G>A | Intron (SNP) | VAF 49/135 reads (36%) | catalogued as COSV100765620; called by muse, mutect2, varscan2
- RBM44 | c.-98-1617G>A | Intron (SNP) | VAF 18/29 reads (62%) | catalogued as rs558399203, COSV57632359; called by muse, mutect2, varscan2
